Somatic mutation profile of cancer-model specimen HCM-BROD-0579-C16-85M (3D Organoid, passage 5; aliquot HCM-BROD-0579-C16-85M-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0579-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 36.9 years (13,485 days).
Specimen HCM-BROD-0579-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e093abe0-b7d8-4131-bfab-8380bfb308bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0579-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0579-C16-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba5f5346-5974-414d-9861-ed070500e88b

The open-access MAF lists 160 somatic variants for this specimen: 120 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 35, Frame Shift Del 6, Frame Shift Ins 5, Intron 3, Nonsense Mutation 3, Splice Region 2, In Frame Del 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCSK1 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 176/380 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852824, CM074404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 231/233 reads (99%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC3 | c.3323C>A p.T1108K | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53330756; called by muse, mutect2, varscan2
- ARHGAP28 | c.1912G>A p.V638M (on ENST00000383472 / NM_001366230.1; = p.V479M on NM_001010000.3) | Missense Mutation (SNP) | VAF 124/250 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV51641653; called by muse, mutect2, varscan2
- ARID5B | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 181/543 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); catalogued as rs145564601, COSV54415348; called by muse, mutect2, varscan2
- ATP10A | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 270/684 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs759620725, COSV63516659; called by muse, mutect2, varscan2
- B4GALT2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 147/406 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1312790665, COSV100530561; called by muse, mutect2, varscan2
- BHLHA9 | c.298A>T p.R100W | Missense Mutation (SNP) | VAF 25/592 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1175843016; called by muse, mutect2
- CCDC102B | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368864406; called by muse, mutect2, varscan2
- CCDC59 | c.154G>C p.G52R | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1565787216; called by muse, mutect2
- CDH8 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 100/317 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.99); catalogued as COSV54872322; called by muse, mutect2, varscan2
- CDS1 | c.789dup p.G264Wfs*7 | Frame Shift Ins (INS) | VAF 88/172 reads (51%) | catalogued as rs759091263; called by mutect2, varscan2
- CHL1 | c.1043G>A p.G348D (on ENST00000397491 / NM_001253387.1; = p.G364D on NM_006614.4) | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.134); catalogued as COSV99062447; called by muse, mutect2, varscan2
- CILP2 | c.2086G>A p.G696S | Missense Mutation (SNP) | VAF 205/542 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs780018968; called by muse, mutect2, varscan2
- CLCN2 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 112/357 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs758247450, COSV99658487; called by muse, mutect2, varscan2
- CLSTN2 | c.2830G>C p.A944P | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV101515847; called by muse, varscan2
- COL6A6 | c.4475G>T p.S1492I | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62031197; called by muse, mutect2
- CRIM1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 71/335 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs560635455, COSV99752611; called by muse, mutect2, varscan2
- CSMD1 | c.9487G>A p.A3163T (on ENST00000520002; = p.A3162T on NM_033225.6) | Missense Mutation (SNP) | VAF 141/144 reads (98%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs747067226, COSV59284416; called by muse, mutect2, varscan2
- CXCR4 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 215/357 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs767830104; called by muse, mutect2, varscan2
- CYP19A1 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 148/370 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV99547865; called by muse, mutect2, varscan2
- CYP2D7 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 45/674 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs3174910; called by muse, mutect2
- CYP4F22 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 110/350 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54111856; called by muse, mutect2, varscan2
- DMAC2 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 219/362 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as rs782251451; called by muse, mutect2, varscan2
- DUOXA1 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 109/433 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs988035611; called by muse, mutect2, varscan2
- EPB41L3 | c.2510C>T p.T837M | Missense Mutation (SNP) | VAF 150/339 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.097); catalogued as rs143141379; called by muse, mutect2, varscan2
- FAM50A | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 165/313 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.947); catalogued as rs370055697; called by muse, mutect2, varscan2
- FSHR | c.1973C>T p.T658I | Missense Mutation (SNP) | VAF 219/309 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs148626637; called by muse, mutect2, varscan2
- FTSJ1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 288/502 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs76994219, COSV99191451; called by muse, mutect2, varscan2
- GAREM1 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 243/481 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as rs867526130; called by muse, mutect2, varscan2
- GNPDA2 | c.126G>A p.G42= | Splice Region (SNP) | VAF 18/85 reads (21%) | catalogued as rs1230830889; called by muse, mutect2, varscan2
- GOPC | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs754533147, COSV50000107; called by muse, mutect2, varscan2
- GPATCH8 | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 91/365 reads (25%) | catalogued as COSV100132787; called by muse, mutect2, varscan2
- LHFPL3 | c.346T>G p.F116V | Missense Mutation (SNP) | VAF 140/1479 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV67813228; called by muse, mutect2
- LILRB2 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 361/589 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs754528432, COSV58744319; called by muse, mutect2, varscan2
- LPO | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 130/437 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757850644, COSV51860612, COSV99229266; called by muse, mutect2, varscan2
- LRFN5 | c.706A>C p.S236R | Missense Mutation (SNP) | VAF 92/314 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1244908019, COSV53247525, COSV53257646; called by muse, mutect2, varscan2
- LRP4 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 177/403 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs1219866663, COSV101066959; called by muse, mutect2, varscan2
- MAGEB10 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 214/408 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63312963; called by muse, mutect2, varscan2
- MAP3K15 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 170/334 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs370633600, COSV58838431; called by muse, mutect2, varscan2
- MMP16 | c.1162T>G p.L388V | Missense Mutation (SNP) | VAF 194/488 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54175920, COSV54189671, COSV99691040; called by muse, mutect2, varscan2
- NFASC | c.3018C>T p.S1006= | Splice Region (SNP) | VAF 218/335 reads (65%) | catalogued as rs866537431; called by muse, mutect2, varscan2
- NOX4 | c.461T>G p.L154R | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as rs1245898497, COSV54455974; called by muse, mutect2, varscan2
- NPAP1 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 219/459 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs776643326, COSV100275102, COSV61508889; called by muse, mutect2, varscan2
- PCDH8 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 234/728 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100131251; called by muse, mutect2, varscan2
- PCDHA7 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 209/391 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.909); catalogued as COSV65342734; called by muse, mutect2, varscan2
- PITPNM1 | c.3515C>T p.A1172V | Missense Mutation (SNP) | VAF 260/596 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.314); catalogued as rs139473273; called by muse, mutect2, varscan2
- PRPS2 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 199/401 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV66126581; called by muse, mutect2, varscan2
- RND2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs183683037; called by muse, mutect2, varscan2
- RNF213 | c.9030G>T p.E3010D | Missense Mutation (SNP) | VAF 85/406 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs192751125; called by muse, mutect2, varscan2
- SIK3 | c.1160G>A p.R387H (on ENST00000445177 / NM_001366686.2; = p.R393H on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/467 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs566690604, COSV52608905, COSV52625598; called by muse, mutect2, varscan2
- SMC2 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs1465589429; called by muse, mutect2, varscan2
- SNTG1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 163/425 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV52436233; called by muse, mutect2, varscan2
- SOX10 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 181/477 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as rs766175657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA31E1 | c.3350C>T p.P1117L | Missense Mutation (SNP) | VAF 151/432 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs372694780, COSV57790718, COSV57794674; called by muse, mutect2
- SRRM2 | c.4565C>T p.S1522L | Missense Mutation (SNP) | VAF 81/500 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1466235721; called by muse, mutect2, varscan2
- SRRT | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 69/860 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747876840; called by muse, mutect2
- TANC1 | c.5134G>A p.G1712S | Missense Mutation (SNP) | VAF 94/415 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs767158516; called by muse, mutect2, varscan2
- TENM4 | c.2078G>A p.R693K | Missense Mutation (SNP) | VAF 135/571 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as rs766879511; called by muse, mutect2, varscan2
- TMPRSS6 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 290/465 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs188371820, COSV60982929; called by muse, mutect2, varscan2
- USP25 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53480687; called by muse, mutect2, varscan2
- VPS52 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 88/335 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.029); catalogued as COSV71403611; called by muse, mutect2, varscan2
- XPA | c.734A>T p.E245V | Missense Mutation (SNP) | VAF 184/275 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1213747369; called by muse, mutect2, varscan2
- ZNF469 | c.9562G>A p.G3188R (on ENST00000437464; = p.G3216R on NM_001367624.2) | Missense Mutation (SNP) | VAF 197/946 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as rs754615656; called by muse, mutect2, varscan2
- ZSCAN1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 348/557 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200190736, COSV56607542; called by muse, mutect2, varscan2
- ACAP2 | c.1856T>G p.L619R | Missense Mutation (SNP) | VAF 140/248 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADAMTS19 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 153/605 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ADH4 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2
- APBA3 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 118/399 reads (30%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASB11 | c.95del p.L32Wfs*4 | Frame Shift Del (DEL) | VAF 31/276 reads (11%) | called by mutect2, pindel, varscan2
- BTBD17 | c.1276C>A p.R426S | Missense Mutation (SNP) | VAF 38/984 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2
- CCL18 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 40/441 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CLEC17A | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.543); called by muse, mutect2
- CLSTN2 | c.2531T>C p.L844P | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTC1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CTNNB1 | c.1553C>A p.A518D | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DLG2 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 137/274 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DNAH1 | c.4445C>T p.S1482F | Missense Mutation (SNP) | VAF 105/215 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- EML1 | c.1910A>G p.D637G | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- FAM210B | c.91_104del p.P31Afs*100 | Frame Shift Del (DEL) | VAF 70/704 reads (10%) | called by mutect2, pindel
- FER1L5 | c.2420T>A p.V807D (on ENST00000623019; = p.V812D on NM_001293083.2) | Missense Mutation (SNP) | VAF 27/401 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FGB | c.254T>G p.V85G | Missense Mutation (SNP) | VAF 163/271 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FGF5 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 130/375 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FMN2 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 269/472 reads (57%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.154); called by muse, mutect2
- FSIP2 | c.8764G>T p.E2922* | Nonsense Mutation (SNP) | VAF 33/328 reads (10%) | called by muse, mutect2, varscan2
- IFNA10 | c.567T>A p.D189E | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL2RB | c.1322dup p.S442Kfs*11 | Frame Shift Ins (INS) | VAF 145/486 reads (30%) | called by mutect2, varscan2
- JPH4 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 257/873 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- LINS1 | c.520dup p.C174Lfs*7 | Frame Shift Ins (INS) | VAF 25/164 reads (15%) | called by mutect2, pindel, varscan2
- LRBA | c.6537_6540del p.P2181Vfs*18 | Frame Shift Del (DEL) | VAF 39/102 reads (38%) | called by mutect2, pindel, varscan2
- MARCHF7 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MCM3AP | c.3980_3997del p.H1327_L1332del | In Frame Del (DEL) | VAF 81/224 reads (36%) | called by mutect2, pindel, varscan2
- METTL16 | c.1003A>T p.T335S | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MSN | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- MYH2 | c.3982_3984del p.E1328del | In Frame Del (DEL) | VAF 42/98 reads (43%) | called by pindel, varscan2
- MYO9A | c.3997C>A p.L1333I | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NEDD4L | c.1871G>T p.R624I (on ENST00000400345 / NM_001144967.3; = p.R604I on NM_015277.6) | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOL8 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 142/210 reads (68%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR1F1 | c.868T>C p.Y290H | Missense Mutation (SNP) | VAF 44/479 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2C1 | c.830T>C p.F277S | Missense Mutation (SNP) | VAF 47/580 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR6N2 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- PIGR | c.1035_1038del p.F345Lfs*14 | Frame Shift Del (DEL) | VAF 122/292 reads (42%) | called by mutect2, pindel, varscan2
- PLA2G4D | c.2233G>T p.V745F | Missense Mutation (SNP) | VAF 139/319 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2
- PLEKHG2 | c.3083C>A p.S1028Y | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2
- PREPL | c.1078_1079del p.V360Sfs*12 | Frame Shift Del (DEL) | VAF 65/363 reads (18%) | called by pindel, varscan2
- PRR13 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- RNF144A | c.840C>A p.C280* | Nonsense Mutation (SNP) | VAF 108/476 reads (23%) | called by muse, mutect2, varscan2
- SLC27A6 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- SLC2A13 | c.1033A>G p.M345V | Missense Mutation (SNP) | VAF 96/1262 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2
- SOX9 | c.1294dup p.Y432Lfs*146 | Frame Shift Ins (INS) | VAF 382/982 reads (39%) | called by mutect2, pindel, varscan2
- SOX9 | c.1507dup p.Y503Lfs*75 | Frame Shift Ins (INS) | VAF 202/529 reads (38%) | called by mutect2, pindel, varscan2
- STRAP | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPAN3 | c.664_667delinsGAT p.I222Dfs*34 | Frame Shift Del (DEL) | VAF 122/315 reads (39%) | called by pindel, varscan2*
- UBN1 | c.2358G>T p.L786F | Missense Mutation (SNP) | VAF 54/910 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- USP34 | c.5483A>T p.K1828M | Missense Mutation (SNP) | VAF 121/517 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- WDFY3 | c.10519C>G p.Q3507E | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by mutect2, varscan2
- WDR24 | c.2118C>A p.H706Q (on ENST00000248142; = p.H576Q on NM_032259.4) | Missense Mutation (SNP) | VAF 28/1048 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF544 | c.1932C>A p.S644R | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF83 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF862 | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 39/309 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ADRB1 | c.882C>T p.A294= | Silent (SNP) | VAF 86/185 reads (46%) | called by muse, mutect2, varscan2
- ATP2B2 | c.1725C>T p.P575= (on ENST00000352432; = p.P541= on NM_001683.5) | Silent (SNP) | VAF 153/320 reads (48%) | catalogued as rs750508666; called by muse, mutect2, varscan2
- CCIN | c.1737G>A p.K579= | Silent (SNP) | VAF 139/211 reads (66%) | called by muse, mutect2, varscan2
- CD1C | c.402A>G p.V134= | Silent (SNP) | VAF 37/326 reads (11%) | called by muse, mutect2, varscan2
- CDH1 | c.1677C>T p.S559= | Silent (SNP) | VAF 209/212 reads (99%) | called by muse, mutect2, varscan2
- CHRNB3 | c.375C>T p.F125= | Silent (SNP) | VAF 146/157 reads (93%) | catalogued as rs1053084474, COSV51494803, COSV99251439; called by muse, mutect2, varscan2
- CRHBP | c.213C>T p.T71= | Silent (SNP) | VAF 221/476 reads (46%) | called by muse, mutect2, varscan2
- DMRT2 | c.192C>T p.D64= | Silent (SNP) | VAF 277/426 reads (65%) | catalogued as rs749640485; called by muse, varscan2
- GATA1 | c.240G>A p.L80= | Silent (SNP) | VAF 180/344 reads (52%) | called by muse, mutect2, varscan2
- GRIA2 | c.1002A>C p.P334= | Silent (SNP) | VAF 72/253 reads (28%) | catalogued as COSV52393268; called by muse, mutect2, varscan2
- IFT140 | c.1395G>A p.A465= | Silent (SNP) | VAF 218/527 reads (41%) | catalogued as rs949232096; called by muse, mutect2, varscan2
- KCNQ2 | c.867C>T p.N289= | Silent (SNP) | VAF 195/495 reads (39%) | catalogued as rs749934609, COSV60434788; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMC3 | c.2094G>T p.G698= | Silent (SNP) | VAF 101/435 reads (23%) | called by muse, mutect2, varscan2
- LMNB1 | c.1140C>G p.L380= | Silent (SNP) | VAF 105/222 reads (47%) | catalogued as COSV54396530; called by muse, mutect2, varscan2
- LRRC15 | c.36C>A p.G12= | Silent (SNP) | VAF 90/296 reads (30%) | called by muse, mutect2, varscan2
- MGAT3 | c.183C>T p.S61= | Silent (SNP) | VAF 402/608 reads (66%) | catalogued as rs776996531, COSV57868898; called by muse, mutect2, varscan2
- NACC1 | c.774G>A p.T258= | Silent (SNP) | VAF 414/626 reads (66%) | catalogued as rs755984117; called by muse, mutect2, varscan2
- PNPLA6 | c.471G>A p.T157= (on ENST00000414982 / NM_001166111.2; = p.T109= on NM_006702.5) | Silent (SNP) | VAF 179/293 reads (61%) | catalogued as rs766433753; called by muse, mutect2, varscan2
- PRR32 | c.759G>T p.P253= | Silent (SNP) | VAF 301/544 reads (55%) | catalogued as COSV100947902, COSV64420509; called by muse, mutect2, varscan2
- PTPRM | c.174T>A p.T58= | Silent (SNP) | VAF 98/205 reads (48%) | called by muse, mutect2, varscan2
- RBM27 | c.2061G>T p.L687= | Silent (SNP) | VAF 32/608 reads (5%) | called by muse, mutect2
- RECQL4 | c.858G>A p.S286= | Silent (SNP) | VAF 329/827 reads (40%) | called by muse, mutect2, varscan2
- RNF169 | c.138G>A p.S46= | Silent (SNP) | VAF 501/988 reads (51%) | catalogued as rs1474085626; called by muse, mutect2, varscan2
- RYR1 | c.7047C>T p.N2349= | Silent (SNP) | VAF 177/491 reads (36%) | catalogued as rs149295336; called by muse, mutect2, varscan2
- SDAD1 | c.1791G>T p.R597= | Silent (SNP) | VAF 18/172 reads (10%) | called by mutect2, varscan2
- SLC16A6 | c.555C>T p.F185= | Silent (SNP) | VAF 125/304 reads (41%) | catalogued as rs141718604; called by muse, mutect2, varscan2
- TCF15 | c.183C>T p.G61= | Silent (SNP) | VAF 51/103 reads (50%) | called by muse, mutect2, varscan2
- TRAM2 | c.129C>T p.A43= | Silent (SNP) | VAF 46/166 reads (28%) | called by muse, mutect2, varscan2
- TRMT10B | c.897G>A p.L299= | Silent (SNP) | VAF 59/236 reads (25%) | catalogued as rs1372408190, COSV53050286; called by muse, mutect2, varscan2
- TSHZ1 | c.1710G>A p.A570= (on ENST00000580243 / NM_001308210.2; = p.A525= on NM_005786.6) | Silent (SNP) | VAF 235/509 reads (46%) | catalogued as rs763038442; called by muse, mutect2, varscan2
- TTN | c.18378A>G p.R6126= (on ENST00000591111; = p.R5199= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/570 reads (3%) | called by muse, mutect2
- WDR86 | c.810G>A p.T270= | Silent (SNP) | VAF 331/551 reads (60%) | catalogued as rs369021299; called by muse, mutect2, varscan2
- ZNF207 | c.519A>C p.G173= | Silent (SNP) | VAF 75/266 reads (28%) | called by muse, mutect2, varscan2
- ZNF729 | c.3201G>A p.K1067= | Silent (SNP) | VAF 178/278 reads (64%) | catalogued as rs779373036; called by muse, mutect2, varscan2
- ZPR1 | c.81C>A p.A27= | Silent (SNP) | VAF 211/916 reads (23%) | catalogued as rs1333125492; called by muse, mutect2, varscan2
- C4orf50 | chr4:5990253 G>T | 5'Flank (SNP) | VAF 93/316 reads (29%) | called by muse, mutect2, varscan2
- IQCK | c.802+36A>T | Intron (SNP) | VAF 196/394 reads (50%) | called by muse, mutect2, varscan2
- NMRAL2P | n.212C>T | RNA (SNP) | VAF 211/337 reads (63%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2170G>T | Intron (SNP) | VAF 47/938 reads (5%) | called by muse, mutect2
- STEAP1B | c.706-18853C>A | Intron (SNP) | VAF 36/579 reads (6%) | called by muse, mutect2
